Gene-level copy-number profile of tumor specimen TARGET-10-PASTHE-09A from TARGET case TARGET-10-PASTHE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,327 days).
Specimen TARGET-10-PASTHE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.287baffe-75c1-54e3-b81d-9a094acf0ad6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASTHE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate.
https://portal.gdc.cancer.gov/files/d12a403e-4a81-4fcf-9f8a-c6d573a8a8fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 653; copy number 1: 86; copy number 2: 56,430; copy number 3: 3,089; copy number 4: 6.

Homozygous deletions (total copy number 0; autosomes only): 133 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:142,440,883–142,786,224, 46 genes: TRBV12-2, TRBV6-5, TRBV7-4, TRBV5-4, TRBV6-6, TRBV7-5, TRBV5-5, TRBV6-7, TRBV7-6, TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,384,255–22,128,103, 30 genes: IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:22,132,553–22,482,959, 26 genes (within-gene range 0–2): TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1.
- chr14:106,531,141–106,622,855, 16 genes: IGHVIII-47-1, IGHV3-48, IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 86. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
